Somatic mutation profile of tumor specimen ALCH-B266-TTP1-A (aliquot ALCH-B266-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B266, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.8 years (22,576 days).
Specimen ALCH-B266-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ba144c9-a0b6-4f97-8083-cf21bf834c99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B266-NB1-A (Blood Derived Normal), aliquot ALCH-B266-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/903fa499-f2f7-499b-934d-01160fc1d61f

The open-access MAF lists 307 somatic variants for this specimen: 211 protein-altering or splice-affecting, 51 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 179, Silent 51, Intron 19, Nonsense Mutation 16, RNA 12, Frame Shift Del 7, 5'UTR 6, Splice Site 5, 3'UTR 4, Frame Shift Ins 3, 5'Flank 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/547 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.843del p.L282Sfs*5 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs587776656, CD982962, COSV58821884, COSV58823674, COSV58823877; ClinVar: pathogenic; called by mutect2, pindel
- ABCG2 | c.1820C>A p.T607K | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52945703; called by muse, varscan2
- ABHD16A | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV65452681; called by muse, mutect2, varscan2
- ADAMTS16 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 32/492 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746490045, COSV57008084; called by muse, mutect2
- AOC1 | c.1358G>C p.R453P | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710720; called by muse, mutect2, varscan2
- AQR | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99334449; called by muse, mutect2, varscan2
- ARSF | c.408C>A p.G136= | Splice Region (SNP) | VAF 35/61 reads (57%) | catalogued as rs769348507; called by muse, mutect2, varscan2
- ARSG | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 101/414 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs532109537; called by muse, mutect2, varscan2
- ASXL3 | c.2557C>A p.P853T | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV52467899; called by muse, mutect2, varscan2
- ATM | c.1555G>T p.V519F | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as rs758056561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC185 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1428730032, COSV100838734; called by muse, mutect2, varscan2
- CCIN | c.1362C>A p.D454E | Missense Mutation (SNP) | VAF 77/479 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58724192; called by muse, mutect2, varscan2
- CDCP2 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747517506, COSV61283850; called by muse, mutect2
- CDH6 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 163/733 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54067583; called by muse, mutect2, varscan2
- CENPE | c.2053G>T p.D685Y | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54382561; called by muse, mutect2, varscan2
- CIITA | c.1939C>G p.R647G | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs372705496; called by muse, mutect2, varscan2
- CROCC2 | c.4799C>A p.P1600Q | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV70675863; called by muse, mutect2, varscan2
- CSMD3 | c.5672G>A p.G1891D (on ENST00000297405 / NM_001363185.1; = p.G1787D on NM_052900.3) | Missense Mutation (SNP) | VAF 16/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1161717855, COSV52195600; called by muse, mutect2
- CWH43 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 105/372 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56937768; called by muse, mutect2, varscan2
- CWH43 | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 106/371 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as COSV99894374; called by muse, mutect2, varscan2
- DOCK7 | c.1143G>C p.K381N | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV99226352; called by muse, mutect2, varscan2
- EPHA6 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.362); catalogued as COSV67561570, COSV67568724, COSV67575935; called by muse, mutect2, varscan2
- FBN3 | c.1817C>T p.T606M | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs930431690; called by muse, mutect2, varscan2
- FBXL16 | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV60964332; called by muse, mutect2, varscan2
- FMN1 | c.4228C>T p.R1410C (on ENST00000616417 / NM_001277313.2; = p.R1187C on NM_001103184.4) | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs866300506, COSV57929513; called by muse, mutect2, varscan2
- GEM | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 74/1369 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs138265181; called by muse, mutect2
- GREM2 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 152/340 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100547929; called by muse, mutect2, varscan2
- HJURP | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100982656, COSV64978964; called by muse, mutect2, varscan2
- HNF4A | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57387702; called by muse, mutect2, varscan2
- ITGAM | c.1588G>T p.D530Y (on ENST00000648685 / NM_001145808.2; = p.D529Y on NM_000632.4) | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54943548; called by muse, mutect2, varscan2
- IVL | c.1153C>A p.H385N | Missense Mutation (SNP) | VAF 81/411 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.342); catalogued as COSV64215369; called by muse, mutect2, varscan2
- KCNG1 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65370212; called by muse, mutect2, varscan2
- KDM3B | c.2135G>T p.S712I | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs773187793; called by muse, mutect2, varscan2
- KEAP1 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 108/206 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50261404; called by muse, mutect2, varscan2
- KIR2DL3 | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 169/293 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV60900921; called by muse, mutect2, varscan2
- KRT3 | c.564C>A p.D188E | Missense Mutation (SNP) | VAF 112/371 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761012956; called by muse, mutect2, varscan2
- MACROD2 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.999); catalogued as rs753910851; called by muse, mutect2, varscan2
- MAP1A | c.7937G>A p.R2646Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs866728176; called by muse, mutect2
- MUC19 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.497); catalogued as rs1409588466; called by muse, mutect2, varscan2
- MYCBP2 | c.7545+1G>T p.X2515_splice (on ENST00000357337; = p.X2553_splice on NM_015057.5) | Splice Site (SNP) | VAF 33/97 reads (34%) | catalogued as COSV62013257, COSV62021372; called by muse, mutect2, varscan2
- MYRFL | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV54914492; called by muse, mutect2
- NFATC1 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs755147641; called by muse, mutect2, varscan2
- NKAPD1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 98/379 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as rs1483326289; called by muse, mutect2, varscan2
- NLGN4Y | c.2000C>A p.T667N | Missense Mutation (SNP) | VAF 191/326 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59299745; called by muse, mutect2, varscan2
- NUP155 | c.1157C>T p.T386M (on ENST00000231498 / NM_153485.3; = p.T327M on NM_004298.4) | Missense Mutation (SNP) | VAF 66/760 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs368991435; called by muse, mutect2
- OR5F1 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1232391290; called by muse, mutect2, varscan2
- OR5W2 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs866404366, COSV60617163; called by muse, mutect2, varscan2
- OTOG | c.1319C>G p.P440R | Missense Mutation (SNP) | VAF 102/407 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.073); catalogued as rs1206817960; called by muse, mutect2, varscan2
- PAPPA | c.1760G>A p.C587Y | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440691926; called by muse, mutect2, varscan2
- PCDHA4 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV63543537; called by muse, mutect2, varscan2
- PIK3C2B | c.4069C>T p.R1357* | Nonsense Mutation (SNP) | VAF 160/568 reads (28%) | catalogued as rs749135149; called by muse, mutect2, varscan2
- PLEKHM2 | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1238826408; called by muse, mutect2, varscan2
- PRG4 | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 97/520 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs761605941, COSV63356245; called by muse, mutect2, varscan2
- PTCHD4 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV59783828; called by muse, mutect2, varscan2
- PXDNL | c.1493A>T p.K498M | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV62476623; called by muse, mutect2, varscan2
- RAG1 | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55025740; called by muse, mutect2, varscan2
- RBM34 | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353788213, COSV100783987; called by muse, mutect2, varscan2
- RIMS1 | c.1701G>T p.L567F | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.375); catalogued as rs1336937885; called by muse, varscan2
- RTF2 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50128608; called by muse, mutect2, varscan2
- SCARB1 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 135/368 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.281); catalogued as rs1380121154, COSV55548657; called by muse, mutect2, varscan2
- SCN10A | c.1918C>T p.Q640* | Nonsense Mutation (SNP) | VAF 56/278 reads (20%) | catalogued as COSV71862532; called by muse, mutect2, varscan2
- SH2D3C | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59124966; called by muse, mutect2, varscan2
- SHPRH | c.2568G>T p.E856D | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99261614; called by muse, varscan2
- SLC6A13 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 61/411 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs140808969, COSV58258894; called by muse, mutect2, varscan2
- SNCA | c.158C>A p.A53E | Missense Mutation (SNP) | VAF 145/503 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as CM146254; called by muse, mutect2, varscan2
- SRCAP | c.8421del p.C2809Vfs*27 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as COSV99350569; called by pindel, varscan2*
- TACR2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200728227, COSV64822603; called by muse, mutect2, varscan2
- TNN | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV53430844; called by muse, mutect2
- TPTE | c.260C>A p.S87* (on ENST00000618007 / NM_199261.4; = p.S69* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 40/410 reads (10%) | catalogued as rs1452854273; called by muse, mutect2, varscan2
- TRIM49 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100316121; called by muse, mutect2, varscan2
- TRPA1 | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 468/727 reads (64%) | catalogued as COSV51574825; called by muse, mutect2, varscan2
- TRPC4 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 121/406 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58990170; called by muse, mutect2, varscan2
- TSC1 | c.2513G>A p.S838N | Missense Mutation (SNP) | VAF 102/517 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1060503208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.50675G>A p.C16892Y (on ENST00000591111; = p.C9468Y on NM_003319.4) | Missense Mutation (SNP) | VAF 64/138 reads (46%) | PolyPhen probably damaging (0.961); catalogued as rs727503599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UCN2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767627359, COSV56476462; called by muse, mutect2, varscan2
- UNC13D | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs760852005, COSV99256119; called by muse, mutect2, varscan2
- WDR26 | c.349G>T p.G117C (on ENST00000414423 / NM_001379403.1; = p.G17C on NM_025160.7) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.01); catalogued as COSV99038984; called by muse, mutect2
- XIRP2 | c.1888G>T p.V630L (on ENST00000628543; = p.V805L on NM_152381.6) | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99748286; called by muse, mutect2, varscan2
- ZBED1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 108/327 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs758632919; called by muse, mutect2, varscan2
- ZNF404 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs1174179545, COSV60988594; called by muse, mutect2, varscan2
- ZNF536 | c.589C>A p.R197S | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777458781, COSV62824044; called by muse, mutect2, varscan2
- ZNF711 | c.2028G>T p.L676F | Missense Mutation (SNP) | VAF 69/96 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52152995; called by muse, mutect2, varscan2
- AADAC | c.1005del p.Y336Mfs*10 | Frame Shift Del (DEL) | VAF 38/95 reads (40%) | called by mutect2, pindel, varscan2
- ACAD9 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACTN4 | c.1380G>C p.E460D | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ADCY4 | c.2554_2555delinsT p.P852Sfs*45 | Frame Shift Del (DEL) | VAF 45/183 reads (25%) | called by pindel, varscan2*
- ADGRL2 | c.3349G>T p.V1117L (on ENST00000370717 / NM_001366005.1; = p.V1104L on NM_012302.4) | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.013); called by muse, varscan2
- ADGRL3 | c.4313C>A p.A1438D (on ENST00000506720 / NM_001322402.2; = p.A1327D on NM_015236.6) | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGAP5 | c.1732G>T p.A578S | Missense Mutation (SNP) | VAF 224/1255 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANKRD29 | c.430-2A>T p.X144_splice | Splice Site (SNP) | VAF 39/199 reads (20%) | called by muse, mutect2, varscan2
- ANKRD45 | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKUB1 | c.1342del p.Q448Kfs*28 | Frame Shift Del (DEL) | VAF 27/164 reads (16%) | called by mutect2, pindel, varscan2
- ARMH1 | c.660C>G p.H220Q | Missense Mutation (SNP) | VAF 53/518 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2
- ASPM | c.6417G>A p.M2139I | Missense Mutation (SNP) | VAF 42/515 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2
- BOD1L1 | c.1289C>G p.S430C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRPF1 | c.1450A>T p.K484* | Nonsense Mutation (SNP) | VAF 30/195 reads (15%) | called by muse, mutect2, varscan2
- C2CD4C | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CAPZA1 | c.832A>T p.K278* | Nonsense Mutation (SNP) | VAF 92/331 reads (28%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CCDC73 | c.59A>T p.E20V | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD1C | c.304C>A p.H102N | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CDH11 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 132/334 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD5 | c.5769C>G p.Y1923* | Nonsense Mutation (SNP) | VAF 46/193 reads (24%) | called by muse, mutect2, varscan2
- CHL1 | c.2501C>A p.P834Q (on ENST00000397491 / NM_001253387.1; = p.P850Q on NM_006614.4) | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- CLEC16A | c.649G>T p.V217F | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CNTN4 | c.2111C>A p.A704E | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- COL22A1 | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 47/405 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.5); called by muse, mutect2
- CPA3 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CUL4B | c.611-1G>T p.X204_splice | Splice Site (SNP) | VAF 86/132 reads (65%) | called by muse, mutect2, varscan2
- DACT2 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCX | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DDHD1 | c.1541C>T p.S514L (on ENST00000323669; = p.S711L on NM_030637.3) | Missense Mutation (SNP) | VAF 68/583 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DNAH10 | c.8316C>A p.S2772R (on ENST00000409039; = p.S2711R on NM_207437.3) | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSC1 | c.1579T>G p.L527V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- E2F7 | c.1829C>G p.T610S | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- EAF2 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ERMARD | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOC1 | c.1192A>T p.T398S | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); called by muse, mutect2
- FANCI | c.1680G>T p.Q560H | Missense Mutation (SNP) | VAF 47/463 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAT3 | c.2251T>A p.Y751N | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FBXL13 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FBXO8 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOXF1 | c.808T>A p.W270R | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOXI2 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.758A>G p.H253R | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GABRA4 | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- GALNT8 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 117/318 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GMPPA | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- GOLM2 | c.1241-2A>T p.X414_splice | Splice Site (SNP) | VAF 50/181 reads (28%) | called by muse, mutect2, varscan2
- GPR141 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GRIA4 | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRIN1 | c.2027C>G p.S676W | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM5 | c.497dup p.N166Kfs*16 | Frame Shift Ins (INS) | VAF 40/168 reads (24%) | called by mutect2, varscan2
- HK3 | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 179/314 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- HMGCLL1 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- HSD17B7 | c.392C>G p.T131S | Missense Mutation (SNP) | VAF 129/341 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- IGFLR1 | c.109A>T p.K37* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- IGHE | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- IGHG2 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 126/766 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- IRS1 | c.829T>A p.S277T | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ISL1 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 221/423 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IST1 | c.530G>A p.R177K (on ENST00000535424 / NM_001270976.1; = p.R164K on NM_014761.4) | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2
- KAT14 | c.2237_2243del p.Y746Cfs*11 | Frame Shift Del (DEL) | VAF 44/162 reads (27%) | called by mutect2, pindel
- KCNAB2 | c.586A>T p.M196L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- KCNJ3 | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL13 | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 96/167 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- LPIN3 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LRP1 | c.7777G>T p.D2593Y | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC36 | c.614G>C p.R205P | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- LRRC37B | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 105/334 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MACF1 | c.18341A>G p.Q6114R (on ENST00000372915; = p.Q4159R on NM_012090.5) | Missense Mutation (SNP) | VAF 66/187 reads (35%) | called by muse, mutect2, varscan2
- MASP2 | c.159dup p.G54Rfs*87 | Frame Shift Ins (INS) | VAF 61/212 reads (29%) | called by mutect2, pindel, varscan2
- MTMR6 | c.855G>T p.L285F | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MUC16 | c.22336A>T p.S7446C | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MUC19 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYH6 | c.3900C>G p.I1300M | Missense Mutation (SNP) | VAF 52/514 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- NEB | c.12691G>T p.D4231Y | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLGN4Y | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 141/312 reads (45%) | called by muse, mutect2, varscan2
- NSMAF | c.154A>C p.I52L | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NT5DC4 | c.1109A>T p.Q370L | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- OR10Q1 | c.154del p.V52Wfs*30 | Frame Shift Del (DEL) | VAF 118/429 reads (28%) | called by mutect2, pindel, varscan2
- OR4M1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 84/415 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAX5 | c.166A>G p.R56G | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCNX2 | c.4229G>T p.W1410L | Missense Mutation (SNP) | VAF 138/677 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PELP1 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGGHG | c.1942A>C p.T648P | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PGLYRP3 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 50/225 reads (22%) | called by muse, mutect2, varscan2
- PIK3R6 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 55/147 reads (37%) | called by muse, mutect2, varscan2
- PIWIL1 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 108/374 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, varscan2
- PKD2L2 | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.449); called by muse, mutect2
- PKM | c.1374G>T p.Q458H | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2
- PKP1 | c.1565T>A p.M522K | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEJ | c.2322C>A p.N774K | Missense Mutation (SNP) | VAF 168/554 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PRTG | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PRUNE2 | c.712G>C p.G238R | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PZP | c.759C>A p.Y253* | Nonsense Mutation (SNP) | VAF 89/274 reads (32%) | called by muse, mutect2, varscan2
- REG1A | c.257C>A p.S86* | Nonsense Mutation (SNP) | VAF 68/370 reads (18%) | called by muse, mutect2
- RGSL1 | c.3063G>T p.R1021S | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- RPL5 | c.14_15dup p.V6Kfs*14 | Frame Shift Ins (INS) | VAF 60/281 reads (21%) | called by mutect2, pindel, varscan2
- RREB1 | c.2549G>C p.C850S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SACS | c.13519C>G p.Q4507E | Missense Mutation (SNP) | VAF 36/355 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SAMD9 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINA9 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 188/624 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC13A5 | c.334C>A p.R112S | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SLC22A12 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 159/531 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SLC9B2 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9C2 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- SNX3 | c.258+2T>A p.X86_splice | Splice Site (SNP) | VAF 64/368 reads (17%) | called by muse, mutect2, varscan2
- SRRM2 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 44/235 reads (19%) | called by muse, mutect2, varscan2
- SS18L1 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- STAC3 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SURF6 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT13 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 169/504 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYT4 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SYT8 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 27/158 reads (17%) | called by muse, mutect2
- THAP12 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, varscan2
- THBS2 | c.2467C>T p.Q823* | Nonsense Mutation (SNP) | VAF 43/380 reads (11%) | called by muse, mutect2, varscan2
- TMIGD2 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- TRAV24 | c.64A>T p.S22C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TRPC7 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.733); called by muse, mutect2
- TTN | c.30396A>C p.K10132N (on ENST00000591111; = p.K9205N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/165 reads (13%) | PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TTN | c.29221T>G p.Y9741D (on ENST00000591111; = p.Y8814D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- U2SURP | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBE3C | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- UGGT1 | c.4532C>G p.P1511R | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- WDR46 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 48/476 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.03); called by muse, mutect2
- ZBTB49 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- ZNF257 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- ZNF727 | c.18C>G p.F6L | Missense Mutation (SNP) | VAF 110/396 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ZSWIM2 | c.785T>C p.F262S | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ADAMTS12 | c.885G>T p.V295= | Silent (SNP) | VAF 76/439 reads (17%) | catalogued as COSV61256087; called by muse, mutect2, varscan2
- ADGRB3 | c.4446C>T p.Y1482= | Silent (SNP) | VAF 52/250 reads (21%) | catalogued as COSV53246279; called by muse, varscan2
- ADGRG4 | c.4368T>A p.S1456= | Silent (SNP) | VAF 136/210 reads (65%) | called by muse, mutect2, varscan2
- ASXL3 | c.4816C>A p.R1606= | Silent (SNP) | VAF 94/278 reads (34%) | catalogued as COSV52469282; called by muse, mutect2, varscan2
- ATP10A | c.3633G>T p.A1211= | Silent (SNP) | VAF 105/343 reads (31%) | catalogued as COSV63523513; called by muse, mutect2, varscan2
- BCAS1 | c.1521C>T p.A507= | Silent (SNP) | VAF 83/487 reads (17%) | catalogued as rs541515385; called by muse, mutect2, varscan2
- CACNA1A | c.4350G>T p.L1450= | Silent (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- CACNA1G | c.606G>A p.T202= | Silent (SNP) | VAF 73/215 reads (34%) | catalogued as rs757652858, COSV61720005; called by muse, mutect2, varscan2
- CCDC185 | c.1563G>T p.V521= | Silent (SNP) | VAF 99/202 reads (49%) | called by muse, mutect2, varscan2
- CFAP43 | c.387C>A p.S129= | Silent (SNP) | VAF 61/241 reads (25%) | catalogued as COSV99530751; called by muse, mutect2, varscan2
- CREBBP | c.744G>T p.P248= | Silent (SNP) | VAF 48/241 reads (20%) | catalogued as COSV52130279; called by muse, mutect2, varscan2
- CSMD3 | c.5673C>A p.G1891= (on ENST00000297405 / NM_001363185.1; = p.G1787= on NM_052900.3) | Silent (SNP) | VAF 16/611 reads (3%) | catalogued as COSV52341394; called by muse, mutect2
- DCAF4L2 | c.309C>A p.T103= | Silent (SNP) | VAF 46/623 reads (7%) | called by muse, mutect2
- DNAH3 | c.8643C>T p.C2881= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs369101432, COSV54540478; called by muse, mutect2, varscan2
- EHBP1 | c.969C>T p.F323= | Silent (SNP) | VAF 73/699 reads (10%) | catalogued as rs188063960, COSV99860232; called by muse, mutect2, varscan2
- EN1 | c.1152G>C p.T384= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV99727374; called by muse, mutect2, varscan2
- FAM13C | c.231C>T p.D77= | Silent (SNP) | VAF 211/681 reads (31%) | called by muse, mutect2, varscan2
- FLG | c.7296G>T p.G2432= | Silent (SNP) | VAF 146/659 reads (22%) | catalogued as rs1411076627; called by muse, mutect2, varscan2
- GAL3ST3 | c.873C>T p.N291= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- GJA4 | c.621C>A p.T207= | Silent (SNP) | VAF 109/359 reads (30%) | called by muse, mutect2, varscan2
- HOXD13 | c.612C>A p.P204= | Silent (SNP) | VAF 154/364 reads (42%) | catalogued as COSV66832951; called by muse, mutect2, varscan2
- IFT80 | c.1470C>T p.I490= | Silent (SNP) | VAF 38/186 reads (20%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.237G>T p.G79= | Silent (SNP) | VAF 208/756 reads (28%) | catalogued as rs757157192; called by muse, mutect2, varscan2
- IL21R | c.213C>A p.A71= | Silent (SNP) | VAF 66/451 reads (15%) | called by muse, mutect2, varscan2
- KASH5 | c.591T>A p.L197= | Silent (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- KIF26B | c.5124G>A p.R1708= | Silent (SNP) | VAF 22/218 reads (10%) | catalogued as rs775432887; called by muse, mutect2, varscan2
- KRT27 | c.1050C>A p.I350= | Silent (SNP) | VAF 56/612 reads (9%) | catalogued as COSV100053222; called by muse, mutect2
- LRCH4 | c.252C>G p.P84= | Silent (SNP) | VAF 97/269 reads (36%) | catalogued as rs200187564, COSV53827147; called by muse, mutect2, varscan2
- MAGEB16 | c.675C>A p.V225= | Silent (SNP) | VAF 58/93 reads (62%) | catalogued as COSV67874683; called by muse, mutect2, varscan2
- NRXN2 | c.2019G>T p.L673= | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- OR2T10 | c.489C>A p.A163= | Silent (SNP) | VAF 219/469 reads (47%) | called by muse, mutect2, varscan2
- OR2T10 | c.207A>T p.I69= | Silent (SNP) | VAF 302/574 reads (53%) | called by muse, mutect2, varscan2
- PALM | c.1107C>T p.S369= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs780716892; called by muse, mutect2
- PCDH11Y | c.1860A>T p.T620= (on ENST00000400457 / NM_032973.2; = p.T609= on NM_032971.3) | Silent (SNP) | VAF 104/184 reads (57%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1014G>T p.V338= | Silent (SNP) | VAF 88/151 reads (58%) | called by muse, mutect2, varscan2
- PFKFB1 | c.1257G>T p.L419= | Silent (SNP) | VAF 102/173 reads (59%) | called by muse, mutect2, varscan2
- PRIMPOL | c.99C>T p.S33= | Silent (SNP) | VAF 82/366 reads (22%) | called by muse, varscan2
- PRMT1 | c.396C>T p.A132= | Silent (SNP) | VAF 31/269 reads (12%) | called by muse, varscan2
- RARRES1 | c.21G>A p.R7= | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as rs1170305344; called by muse, mutect2, varscan2
- RARS1 | c.636G>C p.L212= | Silent (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- REG1A | c.255C>A p.A85= | Silent (SNP) | VAF 69/373 reads (18%) | called by muse, mutect2
- SIGLEC1 | c.582C>T p.T194= | Silent (SNP) | VAF 46/298 reads (15%) | catalogued as rs201521093, COSV52465548; called by muse, mutect2, varscan2
- SIGLEC12 | c.1152G>A p.R384= (on ENST00000291707 / NM_053003.4; = p.R266= on NM_033329.2) | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV52464888; called by muse, mutect2, varscan2
- SIGLEC5 | c.501A>T p.P167= | Silent (SNP) | VAF 80/355 reads (23%) | called by muse, mutect2, varscan2
- SLITRK1 | c.774G>A p.Q258= | Silent (SNP) | VAF 86/281 reads (31%) | called by muse, mutect2, varscan2
- SMR3A | c.159C>T p.P53= | Silent (SNP) | VAF 95/188 reads (51%) | catalogued as COSV56951433; called by muse, mutect2, varscan2
- SPATA31D1 | c.12C>A p.I4= | Silent (SNP) | VAF 43/217 reads (20%) | catalogued as COSV61197058; called by muse, mutect2, varscan2
- TENT5D | c.978C>A p.T326= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as COSV100382673; called by muse, varscan2
- TSNARE1 | c.198G>C p.G66= | Silent (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- TTN | c.94137G>A p.E31379= (on ENST00000591111; = p.E23955= on NM_003319.4) | Silent (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- ZNF534 | c.1332C>T p.I444= (on ENST00000332323 / NM_001143939.3; = p.I431= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV56515564; called by muse, mutect2, varscan2
- AC009533.1 | n.1063G>T | RNA (SNP) | VAF 86/523 reads (16%) | called by muse, mutect2, varscan2
- AC099552.1 | n.202A>G | RNA (SNP) | VAF 69/198 reads (35%) | catalogued as rs768933491; called by muse, mutect2, varscan2
- ADAM22 | c.86-139C>T | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as rs1380968829; called by muse, mutect2
- AP000769.3 | chr11:65503358 ins A | 5'Flank (INS) | VAF 61/272 reads (22%) | called by mutect2, pindel, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 17/98 reads (17%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- ATP2B3 | c.3342+4631C>T | Intron (SNP) | VAF 93/136 reads (68%) | catalogued as rs956750921; called by muse, mutect2, varscan2
- C4orf50 | c.-939G>C | 5'UTR (SNP) | VAF 11/305 reads (4%) | called by muse, mutect2
- CERS5 | c.872+166T>C | Intron (SNP) | VAF 19/243 reads (8%) | called by muse, mutect2
- COBL | c.1096+2086G>C | Intron (SNP) | VAF 96/283 reads (34%) | called by muse, mutect2, varscan2
- COPRS | c.99+281A>G | Intron (SNP) | VAF 89/282 reads (32%) | called by muse, mutect2, varscan2
- CTNND2 | c.2638-1058G>C | Intron (SNP) | VAF 179/294 reads (61%) | called by muse, mutect2, varscan2
- DCHS2 | n.8464C>A | RNA (SNP) | VAF 38/150 reads (25%) | called by muse, mutect2, varscan2
- DDX12P | n.1011G>T | RNA (SNP) | VAF 67/481 reads (14%) | called by muse, mutect2, varscan2
- F13A1 | c.319+72G>T | Intron (SNP) | VAF 86/272 reads (32%) | called by muse, mutect2, varscan2
- FECH | c.-48C>T | 5'UTR (SNP) | VAF 32/156 reads (21%) | called by muse, mutect2, varscan2
- FER1L4 | n.2901G>T | RNA (SNP) | VAF 72/181 reads (40%) | called by muse, mutect2, varscan2
- GLB1L3 | c.812-68C>A | Intron (SNP) | VAF 79/274 reads (29%) | catalogued as COSV66281738; called by muse, mutect2, varscan2
- GLRA2 | c.-64C>T | 5'UTR (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- GOLT1A | c.360+21G>T | Intron (SNP) | VAF 135/254 reads (53%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.454A>T | RNA (SNP) | VAF 58/355 reads (16%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.310G>T | RNA (SNP) | VAF 89/379 reads (23%) | called by muse, mutect2, varscan2
- IL19 | c.-39G>A | 5'UTR (SNP) | VAF 143/577 reads (25%) | called by muse, mutect2, varscan2
- IL2RB | c.204-64A>T | Intron (SNP) | VAF 68/138 reads (49%) | called by muse, mutect2, varscan2
- KDM3A | c.*15G>A | 3'UTR (SNP) | VAF 50/151 reads (33%) | called by muse, mutect2, varscan2
- KHNYN | c.*4360A>G | 3'UTR (SNP) | VAF 14/46 reads (30%) | catalogued as rs770512890; called by muse, mutect2, varscan2
- MAP4 | c.1999+2621G>C | Intron (SNP) | VAF 91/202 reads (45%) | called by muse, mutect2, varscan2
- MST1L | n.351G>T | RNA (SNP) | VAF 34/405 reads (8%) | called by muse, mutect2, varscan2
- NAIP | c.3848-1102C>T | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as rs764171616, COSV52001791; called by muse, mutect2
- OR2L1P | n.991G>T | RNA (SNP) | VAF 29/136 reads (21%) | catalogued as rs770596047; called by muse, mutect2, varscan2
- PDGFRA | c.2156+372C>G | Intron (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- PPP2R3B | c.325-11966G>A | Intron (SNP) | VAF 6/74 reads (8%) | catalogued as rs1287999130; called by muse, mutect2
- PTPRK | c.100+1173G>T | Intron (SNP) | VAF 110/310 reads (35%) | called by muse, mutect2, varscan2
- PYHIN1 | c.579+208G>T | Intron (SNP) | VAF 69/390 reads (18%) | catalogued as rs1051394529; called by muse, mutect2, varscan2
- RN7SL214P | chr15:77918922 T>C | 5'Flank (SNP) | VAF 95/502 reads (19%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159980 G>C | 5'Flank (SNP) | VAF 8/29 reads (28%) | catalogued as rs1278861167; called by muse, mutect2, varscan2
- SNORD114-11 | n.26dup | RNA (INS) | VAF 76/350 reads (22%) | called by mutect2, pindel, varscan2
- TUBB7P | n.187G>T | RNA (SNP) | VAF 45/149 reads (30%) | called by muse, mutect2, varscan2
- UBBP4 | n.781T>A | RNA (SNP) | VAF 236/763 reads (31%) | called by muse, varscan2
- UBE2V1 | c.-5G>T | 5'UTR (SNP) | VAF 4/54 reads (7%) | catalogued as rs956716465; called by muse, mutect2
- UNC5D | c.*2414del | 3'UTR (DEL) | VAF 16/96 reads (17%) | catalogued as rs571534961; called by mutect2, varscan2
- WDR86 | c.163+162T>A | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- Y_RNA | chr14:50089190 C>A | 3'Flank (SNP) | VAF 71/231 reads (31%) | called by muse, mutect2, varscan2
- ZNF493 | c.-132+7946A>G | Intron (SNP) | VAF 54/302 reads (18%) | catalogued as rs1195502947; called by muse, varscan2
- ZNF521 | c.*23G>T | 3'UTR (SNP) | VAF 160/392 reads (41%) | catalogued as rs999289746, COSV100831368; called by muse, varscan2
- ZNF875 | c.314-2662A>T | Intron (SNP) | VAF 65/128 reads (51%) | called by muse, mutect2, varscan2
